Somatic mutation profile of tumor specimen 0DSL0G from CCDI case PBCGTD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Eye, NOS; Age at diagnosis: 1.6 years (571 days).
Specimen 0DSL0G: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5dcb4892-cf61-4976-aa5a-e8aff07ab5b6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSKZF (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/87b36cae-9931-4a85-aaef-63c185638644

The open-access MAF lists 7 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, 5'UTR 1, Silent 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KLF18 | c.584C>T p.T195I | Missense Mutation (SNP) | VAF 63/290 reads (22%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.711); catalogued as rs967054253; called by muse, mutect2, varscan2
- AC244197.3 | c.179G>A p.R60K | Missense Mutation (SNP) | VAF 19/582 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.775); called by muse, mutect2
- THAP9 | c.1544A>G p.N515S | Missense Mutation (SNP) | VAF 24/559 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ZNF578 | c.135G>T p.Q45H | Missense Mutation (SNP) | VAF 246/570 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); called by mutect2, varscan2
- ZFP92 | c.1095G>A p.K365= | Silent (SNP) | VAF 12/220 reads (5%) | called by muse, mutect2
- FAM50A | c.112-30G>T | Intron (SNP) | VAF 7/54 reads (13%) | called by mutect2, varscan2
- SAMHD1 | c.-41del | 5'UTR (DEL) | VAF 26/159 reads (16%) | called by mutect2, pindel, varscan2
